TARGET case TARGET-40-NAAWGB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/a8503e2a-1d50-5d29-a262-73ab5e18ece4

Biospecimens (1 sample)
- Sample TARGET-40-NAAWGB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
